Somatic mutation profile of tumor specimen MMRF_1997_1_BM_CD138pos (aliquot MMRF_1997_1_BM_CD138pos_T1_KHS5U_L08124) from MMRF case MMRF_1997, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 86.7 years (31,682 days).
Specimen MMRF_1997_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6ba62d5-3b0b-4422-bd2d-438d1c503518.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1997_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1997_1_PB_Whole_C2_KHS5U_L08125; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7282c8c6-8daa-4df8-a5d1-be6ae94b058a

The open-access MAF lists 161 somatic variants for this specimen: 63 protein-altering or splice-affecting, 18 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 43, Intron 21, Silent 18, 5'Flank 7, 5'UTR 5, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 2, RNA 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.3242C>T p.P1081L (on ENST00000326724 / NM_001080395.3; = p.P978L on NM_004920.2) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs773490833; called by muse, mutect2, varscan2
- ALDH1L1 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs920919650; called by muse, mutect2, varscan2
- ANKRD27 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60128968, COSV60133068; called by muse, mutect2
- CEACAM19 | c.40A>T p.S14C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV62552300; called by muse, mutect2
- CTU2 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs754595424; called by muse, mutect2
- DEGS2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs1240952412; called by muse, mutect2
- DENND4A | c.3195A>C p.K1065N | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV71265813; called by muse, mutect2
- GNA14 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs756624939, COSV59020348; called by muse, mutect2
- HDC | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs1356084782; called by muse, mutect2
- IGFN1 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as rs538598215, COSV99811072; called by muse, mutect2, varscan2
- IGLV3-1 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); catalogued as rs189772470; called by muse, varscan2
- IGLV3-1 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as rs61731687; called by muse, varscan2
- IGLV3-25 | c.165G>C p.Q55H | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773260070; called by muse, mutect2, varscan2
- IGLV4-69 | c.197A>T p.Y66F | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.242); catalogued as rs566510459; called by muse, mutect2, varscan2
- IGLV4-69 | c.292A>T p.T98S | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.063); catalogued as rs558937590; called by muse, mutect2, varscan2
- KCNB1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779573636, COSV65566374; called by muse, mutect2, varscan2
- KCTD8 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.296); catalogued as COSV63594473; called by muse, mutect2
- LRRTM4 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 118/293 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs1396648231, COSV101297750; called by muse, mutect2, varscan2
- NIBAN1 | c.2525A>C p.E842A | Missense Mutation (SNP) | VAF 23/535 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as rs1355479083; called by muse, mutect2
- NTS | c.135+2T>A p.X45_splice | Splice Site (SNP) | VAF 25/55 reads (45%) | catalogued as COSV55455986; called by muse, mutect2, varscan2
- OR2C3 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs776976495, COSV63576171; called by muse, mutect2, varscan2
- OR2L13 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs553614392, COSV63560530; called by muse, mutect2, varscan2
- RIPK4 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as rs772497449, COSV60190893; called by muse, mutect2, varscan2
- ROCK1 | c.1723A>G p.I575V | Missense Mutation (SNP) | VAF 98/312 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1345685674; called by muse, mutect2, varscan2
- SIRT6 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as rs1417010383; called by muse, mutect2, varscan2
- SLC22A9 | c.1451C>A p.A484D | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54166592; called by muse, mutect2
- SLC35D3 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV59377959; called by muse, mutect2, varscan2
- SLITRK5 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 135/238 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61524808; called by muse, mutect2, varscan2
- SNX15 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV57246269; called by muse, mutect2
- SPARC | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs778156887; called by muse, mutect2, varscan2
- SPEF2 | c.4691T>C p.V1564A | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1326021118, COSV57430524; called by muse, mutect2, varscan2
- UNC80 | c.4982G>A p.R1661Q | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1490619535; called by muse, mutect2
- ADNP | c.806T>C p.M269T | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- BARD1 | c.1913C>G p.A638G | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- BTG1 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- C1GALT1 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 17/357 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); called by muse, mutect2
- CLK1 | c.275A>T p.D92V | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CSF3R | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- DDX17 | c.1996A>T p.T666S | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- DPYSL3 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- FAM180A | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2
- FBXW7 | c.2104T>G p.F702V (on ENST00000281708 / NM_001349798.2; = p.F622V on NM_018315.5) | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXO4 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.364); called by muse, mutect2
- FPGS | c.579+2T>G p.X193_splice | Splice Site (SNP) | VAF 21/683 reads (3%) | called by muse, mutect2
- GFY | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 141/564 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GLI3 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 17/135 reads (13%) | called by muse, mutect2, varscan2
- IFT80 | c.1005_1008del p.D335Efs*7 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- M1AP | c.631A>C p.T211P | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MYG1 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- OR5L2 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 20/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PREX1 | c.1914C>A p.D638E | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRPF8 | c.5139T>A p.S1713R | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2
- RFTN2 | c.818A>T p.K273I | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RRP1 | c.641C>G p.T214S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.216); called by muse, mutect2
- SLC22A31 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SRY | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- STRN3 | c.1803_1810del p.L602Ffs*7 (on ENST00000357479 / NM_001083893.2; = p.L518Ffs*7 on NM_014574.4) | Frame Shift Del (DEL) | VAF 50/148 reads (34%) | called by mutect2, pindel, varscan2
- TBX20 | c.1055C>A p.S352Y | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- TFCP2L1 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2
- TIGD2 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 109/289 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP6NL | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- USP7 | c.967T>A p.L323I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- YLPM1 | c.*36+2T>A | Splice Site (SNP) | VAF 50/377 reads (13%) | called by muse, mutect2, varscan2
- ADAM18 | c.2187C>T p.S729= | Silent (SNP) | VAF 24/257 reads (9%) | catalogued as rs770491457, COSV55846650, COSV55854096; called by muse, mutect2
- AKAP13 | c.714G>A p.P238= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as rs374214307; called by muse, mutect2, varscan2
- ANKAR | c.681C>T p.P227= | Silent (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- CSMD1 | c.9369C>T p.S3123= (on ENST00000520002; = p.S3122= on NM_033225.6) | Silent (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- ERVMER34-1 | c.48T>A p.A16= | Silent (SNP) | VAF 12/201 reads (6%) | catalogued as COSV66920605; called by muse, mutect2
- FLVCR1 | c.1380T>G p.G460= | Silent (SNP) | VAF 20/322 reads (6%) | called by muse, mutect2
- HLA-DPB1 | c.435C>T p.H145= | Silent (SNP) | VAF 35/203 reads (17%) | called by muse, mutect2, varscan2
- IGHD6-25 | c.3G>A p.G1= | Silent (SNP) | VAF 56/74 reads (76%) | catalogued as rs369632440; called by muse, varscan2
- IGHV1-69D | c.282C>T p.S94= | Silent (SNP) | VAF 99/246 reads (40%) | called by muse, mutect2, varscan2
- KDM4D | c.1431G>A p.A477= | Silent (SNP) | VAF 9/229 reads (4%) | catalogued as rs372299295; called by muse, mutect2
- MYDGF | c.150C>T p.S50= | Silent (SNP) | VAF 128/249 reads (51%) | catalogued as rs746466841; called by muse, mutect2, varscan2
- PRDM1 | c.1410G>A p.L470= | Silent (SNP) | VAF 24/405 reads (6%) | catalogued as COSV64844247; called by muse, mutect2
- PRRC2A | c.4779C>T p.G1593= | Silent (SNP) | VAF 7/181 reads (4%) | called by muse, mutect2
- PXDNL | c.3264G>A p.P1088= | Silent (SNP) | VAF 85/224 reads (38%) | catalogued as COSV62486212; called by muse, mutect2, varscan2
- RAB3GAP1 | c.561A>G p.R187= | Silent (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- SLC22A18 | c.42C>T p.P14= | Silent (SNP) | VAF 16/197 reads (8%) | catalogued as rs748975421, COSV100388985; called by muse, mutect2
- TINF2 | c.75A>G p.G25= | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- ZNF521 | c.2973G>T p.R991= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- AATK | c.*657C>T | 3'UTR (SNP) | VAF 61/147 reads (41%) | catalogued as rs1022657503; called by muse, mutect2, varscan2
- ACVR1B | c.*694C>T | 3'UTR (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- ADGRD1 | c.*877T>C | 3'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- ADPGK | chr15:72783936 C>G | 5'Flank (SNP) | VAF 42/144 reads (29%) | called by muse, mutect2, varscan2
- ARHGEF7 | c.1014-713C>T | Intron (SNP) | VAF 94/158 reads (59%) | called by muse, mutect2, varscan2
- ART4 | c.*720G>A | 3'UTR (SNP) | VAF 7/100 reads (7%) | catalogued as rs1228321326; called by muse, mutect2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 58/142 reads (41%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- BOC | c.376+497T>C | Intron (SNP) | VAF 6/105 reads (6%) | called by muse, mutect2
- CASKIN1 | c.*800C>T | 3'UTR (SNP) | VAF 13/178 reads (7%) | called by muse, mutect2
- CEP290 | c.6012-75T>G | Intron (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- CHD6 | c.*847del | 3'UTR (DEL) | VAF 17/124 reads (14%) | called by mutect2, pindel, varscan2
- CHL1 | c.*83G>A | 3'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- CLDN16 | c.*415C>T | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- COPS2 | chr15:49155754 C>A | 5'Flank (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- DNAJB5 | c.-34-148C>A | Intron (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- ECHDC1 | c.381+468A>G | Intron (SNP) | VAF 21/101 reads (21%) | catalogued as rs775320980; called by muse, mutect2, varscan2
- FAM13A | c.759+680C>T | Intron (SNP) | VAF 25/103 reads (24%) | catalogued as rs996563882; called by muse, mutect2, varscan2
- FAM149A | c.*559G>A | 3'UTR (SNP) | VAF 24/117 reads (21%) | catalogued as rs566527252; called by muse, mutect2, varscan2
- FCER2 | c.-30C>A | 5'UTR (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- FMN1 | c.*72T>C | 3'UTR (SNP) | VAF 38/928 reads (4%) | called by muse, mutect2
- FOXC1 | c.*1464C>A | 3'UTR (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- FOXG1 | c.-7C>G | 5'UTR (SNP) | VAF 21/88 reads (24%) | catalogued as rs769086783; called by muse, mutect2, varscan2
- FUNDC2 | c.*4910C>G | 3'UTR (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- FUNDC2 | c.*4911T>C | 3'UTR (SNP) | VAF 4/46 reads (9%) | catalogued as rs1397487506; called by muse, mutect2
- GCSAM | c.*2366A>T | 3'UTR (SNP) | VAF 60/122 reads (49%) | called by mutect2, varscan2
- GCSAM | c.*2349_*2363del | 3'UTR (DEL) | VAF 55/121 reads (45%) | called by mutect2, pindel, varscan2
- GGA2 | c.*302A>G | 3'UTR (SNP) | VAF 17/195 reads (9%) | called by muse, mutect2
- GIMAP4 | c.*267A>C | 3'UTR (SNP) | VAF 11/141 reads (8%) | called by muse, mutect2
- GLI2 | c.*1544C>T | 3'UTR (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- GRIP2 | c.782-130G>T | Intron (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- IRF4 | c.*3180G>A | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.*301T>C | 3'UTR (SNP) | VAF 19/57 reads (33%) | catalogued as rs1235112924; called by muse, mutect2, varscan2
- LAX1 | c.*1056A>T | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- LTB | c.162+120G>A | Intron (SNP) | VAF 22/55 reads (40%) | catalogued as rs570615074, COSV53002683; called by muse, mutect2, varscan2
- MAP4 | c.1999+2874A>G | Intron (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- MAP4K4 | chr2:101697990 G>C | 5'Flank (SNP) | VAF 66/195 reads (34%) | called by muse, mutect2, varscan2
- MAST4 | c.*1572T>A | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- MGST1 | c.222-82T>A | Intron (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- MIR5195 | chr14:106851186 C>T | 5'Flank (SNP) | VAF 100/251 reads (40%) | catalogued as rs775659782; called by muse, mutect2, varscan2
- MTMR6 | c.*1166A>T | 3'UTR (SNP) | VAF 47/75 reads (63%) | called by muse, mutect2, varscan2
- MYO1H | c.2824+9T>C | Intron (SNP) | VAF 14/149 reads (9%) | called by muse, mutect2
- NDUFA5 | chr7:123557833 G>A | 5'Flank (SNP) | VAF 29/860 reads (3%) | called by muse, mutect2
- NDUFC2 | c.-84C>T | 5'UTR (SNP) | VAF 38/450 reads (8%) | catalogued as rs1370417459; called by muse, mutect2
- NFATC2 | c.-78G>A | 5'UTR (SNP) | VAF 13/224 reads (6%) | catalogued as COSV101371005; called by muse, mutect2
- NGRN | c.*14T>G | 3'UTR (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- NPR3 | chr5:32710493 T>C | 5'Flank (SNP) | VAF 74/142 reads (52%) | called by muse, mutect2, varscan2
- NUB1 | c.*619T>G | 3'UTR (SNP) | VAF 50/105 reads (48%) | called by muse, mutect2, varscan2
- NUCKS1 | c.*824T>C | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- ONECUT2 | c.*9752G>A | 3'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- OR7E5P | n.324G>A | RNA (SNP) | VAF 27/307 reads (9%) | called by muse, mutect2
- PGAP1 | c.-17G>C | 5'UTR (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- PIGP | c.154+200T>C | Intron (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- PKD1L2 | n.2650C>T | RNA (SNP) | VAF 11/24 reads (46%) | catalogued as rs781408458; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.*510A>T | 3'UTR (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- PRDM16 | c.*1910C>T | 3'UTR (SNP) | VAF 33/92 reads (36%) | catalogued as rs778016708; called by muse, mutect2, varscan2
- PRKD1 | c.*87T>G | 3'UTR (SNP) | VAF 35/88 reads (40%) | called by muse, mutect2, varscan2
- PTCD3 | c.*3108A>T | 3'UTR (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- RANBP6 | c.*987T>A | 3'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- RBM22 | c.54+124C>T | Intron (SNP) | VAF 59/180 reads (33%) | called by muse, mutect2, varscan2
- REG4 | c.165+127G>C | Intron (SNP) | VAF 8/246 reads (3%) | called by muse, mutect2
- ROBO3 | c.2987-49C>T | Intron (SNP) | VAF 38/430 reads (9%) | catalogued as rs776418988; called by muse, mutect2
- RPL27A | c.*2782A>G | 3'UTR (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- SDE2 | c.*378T>G | 3'UTR (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- SIDT1 | c.747+111C>T | Intron (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- SLC35B4 | c.*5371A>C | 3'UTR (SNP) | VAF 12/139 reads (9%) | called by muse, mutect2
- SSTR1 | c.*647C>T | 3'UTR (SNP) | VAF 68/140 reads (49%) | called by muse, mutect2, varscan2
- TAF3 | c.*1322G>A | 3'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- TGFB1I1 | c.14-65T>G | Intron (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- TLE3 | c.25-95C>T | Intron (SNP) | VAF 21/192 reads (11%) | called by muse, mutect2, varscan2
- TM4SF18 | c.*94T>C | 3'UTR (SNP) | VAF 18/598 reads (3%) | catalogued as rs1324193902; called by muse, mutect2
- TMEM41B | c.*301C>A | 3'UTR (SNP) | VAF 4/100 reads (4%) | called by muse, mutect2
- TXLNB | c.1077+61G>T | Intron (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2, varscan2
- UNC13D | c.2447+117C>T | Intron (SNP) | VAF 43/99 reads (43%) | catalogued as rs1002149227; called by muse, mutect2, varscan2
- VPS13D | c.*2510C>A | 3'UTR (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- WHAMMP2 | chr15:28763731 G>A | 3'Flank (SNP) | VAF 14/46 reads (30%) | catalogued as rs1469728684; called by muse, mutect2, varscan2
- WHAMMP3 | chr15:22690739 G>A | 3'Flank (SNP) | VAF 17/184 reads (9%) | catalogued as rs1358469950; called by muse, mutect2, varscan2
- XBP1 | c.*899G>A | 3'UTR (SNP) | VAF 9/85 reads (11%) | catalogued as COSV53275018; called by muse, mutect2, varscan2
- ZBTB44 | c.*3554del | 3'UTR (DEL) | VAF 30/101 reads (30%) | called by mutect2, pindel, varscan2
- ZNF564 | c.*694A>T | 3'UTR (SNP) | VAF 11/166 reads (7%) | called by muse, mutect2
- ZNF655 | c.136+3575T>G | Intron (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
